Surgical pathology report (de-identified scan), TCGA case TCGA-UD-AAC1, project TCGA-MESO (Mesothelioma), tissue source site  University of Western Australia, specimen TCGA-UD-AAC1-01A (Primary Tumor).

[page 1 of 2]
[Redacted]		[Redacted]		Printed
DOB: [Redacted]	Sex: F	M		[Redacted]

CLINICAL HISTORY:

Right mesothelioma.

MACROSCOPIC:

Right pleural mesothelioma: Roughly triangular shaped piece of pleural tissue measuring 100mm x 70mm and up to 15mm in thickness. The surfaces appear nodular and irregular with some haemorrhage present on both surfaces. The pleura appears thinner towards the tailing narrow end which measures up to 35mm. There appears to be a cut through the nodular thickened area. The cut surface shows a lobulated and whorled grey tan yellowish cut surface focally. Specimen is sliced from the thicker end to the thinner and the cut surface is relatively homogeneous from one end to the other (A-G 7x1, H 1xM,

MICROSCOPIC:

Sections show the specimen to be almost entirely infiltrated by a malignant tumour. The tumour is forming nests and poorly formed glandular structures and is composed of epithelioid cells with round nuclei, prominent nucleoli and abundant eosinophilic cytoplasm. The tumour infiltrates from the pleural surface through fat and focally is seen at the deep margin of the biopsy. Geographic areas of necrosis are evident. A focal papillary pattern is seen along the surface.

Norm
File
Note
Requi
Patie
Notifi
Patie
Will C
Mak
Appoint
Colle
Prescrip
On Cos
Treatm
Check
Doct

Page 1 of 2

M

Confidentiality: This document is confidential. If you are not the intended recipient you must not read, copy, distribute or act in reliance on it. If you have received this document in error please notify us immediately and destroy the original message.

ICD-O-3

Mesothelioma, epithelioid
malignant 9052/3

Site: (R) Pleura C38.4

JW 1/29/14

[page 2 of 2]
[REDACTED]		[REDACTED]		Printed
DOB:	Sex: F	M		[REDACTED]

- 2 -

Immunoperoxidase stains show strong staining with Cam5.2 and calretinin, weaker staining with CD5/6 and no staining with CEA or BerEp4.

CONCLUSION:

Right pleural lesion: Deeply invasive malignant mesothelioma. Tumour extends up to the deep margin of excision.

Pathologist:

Page 2 of 2

Norm File
Note Requi
Patie Notif
Patie Will C
Mal Appoin
Colle Prescrip
On Co Treatm
Check Doct

M

Confidentiality: This document is confidential. If you are not the intended recipient you must not read, copy, distribute or act in reliance on it. If you have recieved this document in error please notify us immediately and destroy the original message.

DQ - for unknown details (when, what type) regarding pleurodesis

Criteria	W 11/8/13	Yes	No

Source: NCI Genomic Data Commons file a4ab74c9-21dd-46c9-9ba5-83a263695339 (TCGA-UD-AAC1.97EA8988-20F9-4E07-B2A5-C0B584DAC700.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).